Somatic mutation profile of tumor specimen MP2PRT-PAVYXX-TMP1-A (aliquot MP2PRT-PAVYXX-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVYXX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.5 years (900 days).
Specimen MP2PRT-PAVYXX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a2a56e5-b819-4777-96d7-f756d4c2cb8e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVYXX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVYXX-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6414ee15-20d3-49a9-8b58-0375c974c5b1

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TXNDC11 | c.2725G>A p.D909N (on ENST00000356957 / NM_001303447.2; = p.D882N on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 94/533 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as rs201416434; called by muse, mutect2, varscan2
- UHRF1 | c.721G>A p.A241T (on ENST00000612630 / NM_001290050.1; = p.A254T on NM_013282.4) | Missense Mutation (SNP) | VAF 76/516 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.505); catalogued as COSV53577199; called by muse, mutect2, varscan2
- SETD2 | c.2486_2487insCTTT p.L829Ffs*10 | Frame Shift Ins (INS) | VAF 28/148 reads (19%) | called by pindel, varscan2
- HOXB3 | c.1194C>T p.H398= | Silent (SNP) | VAF 86/514 reads (17%) | catalogued as rs779773513; called by muse, mutect2, varscan2
- MYO16 | c.3810G>A p.P1270= | Silent (SNP) | VAF 53/753 reads (7%) | catalogued as rs776121170, COSV62750192; called by muse, mutect2
